MMRF case MMRF_2292 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/15d6bcd0-5cf9-4971-84a3-3eaa990a7b37

Demographics
Sex at birth: female; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.0 years (27,027 days); ISS stage: II; Days to last known disease status: 836 days (2.3 years); Days to last follow up: 836 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 1): M Protein 2.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.4 mg/dL; Immunoglobulin G 44.7 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 8.9 g/dL; Glucose 6.05 mmol/L; C-Reactive Protein 0.189 mg/dL.
- Day 92 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 5.92 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 185: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.28 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 7.54 mmol/L.
- Day 269 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 6.11 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 39.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 6.38 mmol/L.
- Day 394 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 7.94 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 355 ×10⁹/L; Creatinine 42.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 8.03 mmol/L.
- Day 458 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 6.83 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 9.79 mmol/L.
- Day 542 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 7.1 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 4.57 mmol/L.
- Day 639 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 8.71 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 8.1 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 4.35 mmol/L.
- Day 753 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 9.94 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.5 mmol/L.
- Day 836 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day -20: Weight: 97 kg; Height: 158 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2292_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2292_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
